Gene-level copy-number profile of tumor specimen TCGA-96-8170-01A from TCGA case TCGA-96-8170, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.4 years (27,558 days).
Specimen TCGA-96-8170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2bd49c6b-e34d-4016-a232-57b4d71e6863.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-96-8170-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/18bcdc33-dd8e-4df2-91ac-cfb2477bab78

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 2: 8,509; copy number 3: 197; copy number 4: 44,464; copy number 5: 96; copy number 6: 5,784; copy number 10: 17; copy number 11: 455; copy number 12: 255.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-96-8170-01A-11D-2292-01): tumor purity 0.35, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–24,592,104, 36 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.
- chr9:37,915,898–38,069,227, 1 gene (within-gene range 0–2): SHB.
- chr9:38,147,428–38,147,561, 1 gene: U8.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 727 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 11–12 (broad region; genes not listed).
- chr9:33,019,682–33,473,930, 17 genes, copy number 10: LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2, AQP3, AL356218.1, NOL6, MIR6851.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
